Somatic mutation profile of tumor specimen 0DW746 from CCDI case PBCNJH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.0 years (5,860 days).
Specimen 0DW746: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01e74e11-5f7c-4e6b-8d7a-88434db76b23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW72N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66883e75-3b6f-48b7-871f-0394ece89da3

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MDN1 | c.5528G>A p.R1843Q | Missense Mutation (SNP) | VAF 194/478 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411698857, COSV65521248; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1760C>T p.T587M | Missense Mutation (SNP) | VAF 132/621 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1043618753; called by muse, varscan2
